Gene-level copy-number profile of tumor specimen TCGA-ZM-AA0N-01A from TCGA case TCGA-ZM-AA0N, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 44.1 years (16,094 days).
Specimen TCGA-ZM-AA0N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.3971af8c-28f9-470b-995a-a98c75241d10.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZM-AA0N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/70363e94-1136-42a3-ac41-a00525d8f068

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 859; copy number 2: 15,557; copy number 3: 17,722; copy number 4: 15,303; copy number 5: 6,537; copy number 6: 1,430; copy number 7: 1,407; copy number 8: 826; copy number 9: 172.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZM-AA0N-01A-21D-A434-01): tumor purity 0.33, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,405 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,211,632–171,251,857, 799 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:70,972–40,099,580, 719 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:67,849,044–69,660,915, 18 genes, copy number 7: NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1.
- chr8:69,700,224–69,700,495, 1 gene, copy number 7: RN7SKP29.
- chr12:66,767–34,249,958, 850 genes, copy number 7–9 (broad region; genes not listed).
- chr21:17,901,263–19,621,545, 18 genes, copy number 8 (within-gene range 6–8): CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3.

Autosomal genes at a single copy (total copy number 1): 545. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
